Somatic mutation profile of tumor specimen ALCH-AEJT-TTP1-A (aliquot ALCH-AEJT-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEJT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.1 years (24,146 days).
Specimen ALCH-AEJT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11194bc3-f616-4b48-bafd-9d93f59c0f31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEJT-NB1-A (Blood Derived Normal), aliquot ALCH-AEJT-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f54693a-7212-4594-8d2b-28ca23423e9f

The open-access MAF lists 139 somatic variants for this specimen: 93 protein-altering or splice-affecting, 28 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 28, Intron 8, Nonsense Mutation 8, Frame Shift Del 6, RNA 4, 3'Flank 3, Splice Region 2, 5'Flank 2, Frame Shift Ins 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 337/739 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NBN | c.2184+1G>T p.X728_splice | Splice Site (SNP) | VAF 260/483 reads (54%) | catalogued as rs756363734; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 130/345 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs375219268; called by muse, mutect2, varscan2
- AHSG | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as rs1282468635; called by muse, mutect2, varscan2
- ANXA11 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.172); catalogued as COSV55415422; called by muse, mutect2
- CNGB3 | c.646C>A p.R216= | Splice Region (SNP) | VAF 52/688 reads (8%) | catalogued as CM050551, COSV60686900; called by muse, mutect2
- E2F8 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs760381605, COSV51462486; called by mutect2, varscan2
- FRMPD1 | c.4485G>T p.Q1495H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV66700629; called by muse, mutect2, varscan2
- GPR26 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 65/439 reads (15%) | catalogued as COSV52932808; called by muse, mutect2, varscan2
- GYPC | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 21/406 reads (5%) | catalogued as COSV52146425; called by muse, mutect2
- HDAC9 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs769091094; called by muse, mutect2, varscan2
- JAKMIP1 | c.1459C>A p.R487S | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51545691; called by muse, mutect2, varscan2
- KRTAP13-1 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV100819838, COSV62662833; called by muse, mutect2, varscan2
- LRP1B | c.11833G>A p.G3945R | Missense Mutation (SNP) | VAF 182/585 reads (31%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.999); catalogued as rs770860780, COSV67196685; called by muse, mutect2, varscan2
- LZTS1 | c.1345G>T p.V449F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1428318981; called by muse, mutect2, varscan2
- MAP4K4 | c.3292G>A p.D1098N (on ENST00000347699 / NM_001242559.2; = p.D1016N on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56333964; called by muse, mutect2
- NLRP14 | c.909A>T p.L303F | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100205000; called by muse, mutect2, varscan2
- OR1F1 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 56/350 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs758873218, COSV100484334; called by muse, mutect2, varscan2
- PCDHB14 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as rs1554289521; called by muse, mutect2, varscan2
- PSG7 | c.201G>C p.W67C | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414362693; called by muse, mutect2, varscan2
- RPN1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759305274, COSV56189900; called by muse, mutect2
- RYR2 | c.4603C>A p.P1535T | Missense Mutation (SNP) | VAF 153/366 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100769615, COSV63660633; called by muse, mutect2, varscan2
- SBF1 | c.4834G>A p.V1612M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as rs370715026; called by muse, varscan2
- SPATA7 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 240/581 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1258488697; called by muse, mutect2, varscan2
- SYN3 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 74/256 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs527740515; called by muse, varscan2
- ZFAND6 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.092); catalogued as rs753726703; called by muse, mutect2, varscan2
- ABCB1 | c.3377G>T p.S1126I | Missense Mutation (SNP) | VAF 85/414 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AKR1B1 | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 142/356 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANKRD44 | c.1664del p.T555Kfs*19 | Frame Shift Del (DEL) | VAF 51/151 reads (34%) | called by mutect2, pindel, varscan2
- ANO3 | c.2074T>A p.C692S | Missense Mutation (SNP) | VAF 129/567 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APC | c.6016G>A p.G2006S | Missense Mutation (SNP) | VAF 279/682 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASB2 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- BTRC | c.1187T>A p.M396K (on ENST00000370187 / NM_033637.4; = p.M360K on NM_003939.5) | Missense Mutation (SNP) | VAF 198/588 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1GALT1C1 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CARM1 | c.464A>T p.Y155F | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CCDC88C | c.5910del p.Q1971Rfs*94 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- CLEC2A | c.23A>C p.D8A | Missense Mutation (SNP) | VAF 125/342 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CRACD | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- CUBN | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 240/760 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2
- EDA | c.204dup p.R69Afs*31 | Frame Shift Ins (INS) | VAF 45/130 reads (35%) | called by mutect2, pindel, varscan2
- EFHB | c.143T>A p.V48E | Missense Mutation (SNP) | VAF 85/529 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- F9 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 229/472 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FAM170A | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- FXR1 | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- GLG1 | c.2667G>A p.K889= | Splice Region (SNP) | VAF 82/191 reads (43%) | called by muse, mutect2, varscan2
- GSTK1 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- JAML | c.443G>T p.G148V (on ENST00000356289 / NM_001098526.2; = p.G138V on NM_153206.3) | Missense Mutation (SNP) | VAF 88/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KBTBD7 | c.1500C>G p.S500R | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KERA | c.647T>A p.M216K | Missense Mutation (SNP) | VAF 152/525 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KLRC1 | c.481del p.E161Kfs*3 | Frame Shift Del (DEL) | VAF 175/563 reads (31%) | called by mutect2, pindel, varscan2
- KRT75 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 111/351 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- LCE1C | c.252G>T p.R84S | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAGED2 | c.1711G>T p.A571S | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by mutect2, varscan2
- MAP3K3 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MBD6 | c.2417_2418del p.E806Afs*41 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | called by pindel, varscan2
- MYH15 | c.4376T>G p.L1459R | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO16 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NTRK3 | c.1766C>A p.A589D | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR51A2 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 152/382 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR56B1 | c.938del p.K313Rfs*10 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by pindel, varscan2
- OTUD7A | c.1408del p.A470Qfs*66 (on ENST00000307050 / NM_001382637.1; = p.A463Qfs*66 on NM_130901.3) | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel, varscan2
- PHLDB3 | c.1655G>C p.R552P | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.4360G>T p.G1454* | Nonsense Mutation (SNP) | VAF 39/67 reads (58%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3856C>T p.Q1286* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- PRR14L | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PRRC2C | c.4085C>A p.S1362* (on ENST00000367742; = p.S1360* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 68/214 reads (32%) | called by muse, mutect2, varscan2
- PXDNL | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAB3IP | c.326G>T p.C109F (on ENST00000550536 / NM_175623.4; = p.C93F on NM_022456.5) | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- REST | c.1593T>A p.H531Q | Missense Mutation (SNP) | VAF 93/509 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REST | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 93/509 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- RYR2 | c.10754C>A p.A3585D | Missense Mutation (SNP) | VAF 175/303 reads (58%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SEMA6D | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 71/356 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SLC22A8 | c.1370G>T p.S457I | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC27A6 | c.1038A>T p.R346S | Missense Mutation (SNP) | VAF 244/661 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SLFN5 | c.2600C>A p.A867D | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STK11 | c.714_719del p.I238_S240delinsM | In Frame Del (DEL) | VAF 14/18 reads (78%) | called by mutect2, varscan2
- STK36 | c.2812C>A p.Q938K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2
- STRAP | c.641dup p.L214Ffs*5 | Frame Shift Ins (INS) | VAF 35/173 reads (20%) | called by mutect2, pindel, varscan2
- SV2C | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SVOPL | c.849G>T p.Q283H (on ENST00000419765; = p.Q131H on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SYNPO | c.2367C>A p.Y789* (on ENST00000394243 / NM_001166208.2; = p.Y545* on NM_007286.6) | Nonsense Mutation (SNP) | VAF 18/324 reads (6%) | called by muse, mutect2
- TENM1 | c.4182G>C p.R1394S | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TENM3 | c.3136C>A p.Q1046K | Missense Mutation (SNP) | VAF 35/559 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- TG | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- THSD4 | c.2391G>T p.W797C | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOX2 | c.604C>A p.P202T (on ENST00000358131 / NM_001098798.2; = p.P151T on NM_032883.3) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TRIM35 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM49B | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 34/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSHR | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC14 | c.2078C>T p.S693L | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- UGT2B10 | c.717A>T p.L239F | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, varscan2
- ZNF585A | c.369G>C p.M123I (on ENST00000292841 / NM_001288800.2; = p.M68I on NM_152655.3) | Missense Mutation (SNP) | VAF 161/385 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF835 | c.1127A>C p.H376P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ABHD3 | c.570T>C p.Y190= | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as rs1329779179, COSV100004157; called by muse, mutect2, varscan2
- ACVR1B | c.1410G>T p.G470= | Silent (SNP) | VAF 47/160 reads (29%) | called by muse, mutect2, varscan2
- ALPP | c.441C>T p.R147= | Silent (SNP) | VAF 20/187 reads (11%) | catalogued as rs550577575; called by muse, mutect2
- BEST3 | c.999G>A p.K333= | Silent (SNP) | VAF 92/294 reads (31%) | catalogued as rs773273015; called by muse, mutect2, varscan2
- CDSN | c.1056C>A p.S352= | Silent (SNP) | VAF 40/241 reads (17%) | called by muse, mutect2, varscan2
- CHPF | c.2046C>T p.S682= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs1189739945, COSV60534921; called by muse, mutect2, varscan2
- CHRM4 | c.543C>T p.P181= | Silent (SNP) | VAF 44/185 reads (24%) | catalogued as rs752117216; called by muse, mutect2, varscan2
- CTAG2 | c.189T>G p.G63= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- INSRR | c.1726C>A p.R576= | Silent (SNP) | VAF 213/307 reads (69%) | catalogued as rs762538907, COSV63871856; called by muse, mutect2, varscan2
- ITGB4 | c.291G>T p.R97= | Silent (SNP) | VAF 60/143 reads (42%) | called by muse, mutect2, varscan2
- KCNA5 | c.564G>A p.P188= | Silent (SNP) | VAF 34/192 reads (18%) | catalogued as rs199597465, COSV99363844; called by muse, mutect2, varscan2
- LRRC30 | c.330C>T p.P110= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs1475114115, COSV67302523; called by muse, mutect2, varscan2
- MPPED1 | c.165C>A p.T55= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV61987340; called by muse, mutect2, varscan2
- NOD1 | c.2817G>A p.E939= | Silent (SNP) | VAF 185/458 reads (40%) | catalogued as rs769101053, COSV56110977; called by muse, mutect2, varscan2
- OR2J2 | c.348G>A p.L116= | Silent (SNP) | VAF 134/220 reads (61%) | called by muse, mutect2, varscan2
- PACRG | c.738C>A p.S246= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100435419; called by muse, mutect2, varscan2
- PCDHB13 | c.1917G>A p.R639= | Silent (SNP) | VAF 98/440 reads (22%) | catalogued as COSV53395441; called by muse, mutect2, varscan2
- PDHA2 | c.34C>A p.R12= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV54781055, COSV99756891; called by muse, mutect2, varscan2
- PLCH1 | c.4260A>T p.I1420= (on ENST00000340059 / NM_001130960.2; = p.I1412= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/254 reads (17%) | called by muse, mutect2, varscan2
- RPL27A | c.309G>T p.V103= | Silent (SNP) | VAF 72/330 reads (22%) | called by mutect2, varscan2
- SLC2A6 | c.1131C>T p.S377= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs782433226, COSV52468656; called by muse, mutect2, varscan2
- SLITRK2 | c.42C>A p.A14= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV59427981; called by muse, mutect2, varscan2
- SMAD3 | c.372C>T p.P124= | Silent (SNP) | VAF 87/441 reads (20%) | catalogued as COSV59283767; called by muse, mutect2, varscan2
- STAP2 | c.201A>G p.A67= | Silent (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- TNIK | c.2661C>A p.T887= | Silent (SNP) | VAF 40/294 reads (14%) | called by muse, mutect2, varscan2
- TRAF3 | c.1113G>T p.A371= | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as COSV100693639; called by muse, mutect2, varscan2
- UMOD | c.1902C>T p.T634= | Silent (SNP) | VAF 177/508 reads (35%) | catalogued as rs766780246, COSV56778560; called by muse, mutect2, varscan2
- ZFHX2 | c.7036C>T p.L2346= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-16664C>A | Intron (SNP) | VAF 51/150 reads (34%) | called by muse, mutect2, varscan2
- ADAM6 | n.1534G>T | RNA (SNP) | VAF 99/202 reads (49%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826512 C>A | 3'Flank (SNP) | VAF 140/665 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502745 del TA | 5'Flank (DEL) | VAF 78/378 reads (21%) | called by pindel, varscan2
- AP000769.3 | chr11:65502918 G>A | 5'Flank (SNP) | VAF 187/418 reads (45%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+221C>A | Intron (SNP) | VAF 20/94 reads (21%) | catalogued as COSV61449959; called by muse, mutect2, varscan2
- CAMK2D | c.414+1006A>T | Intron (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- EYS | c.1767-6744C>A | Intron (SNP) | VAF 95/616 reads (15%) | called by muse, mutect2, varscan2
- FAIM2 | c.-13G>C | 5'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, varscan2
- IQSEC2 | c.738-10811G>T | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- LILRB5 | c.1306+23C>A | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40541624 A>C | 3'Flank (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- OR2U1P | n.659C>T | RNA (SNP) | VAF 85/604 reads (14%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156794 G>T | 3'Flank (SNP) | VAF 93/280 reads (33%) | called by muse, mutect2, varscan2
- PNCK | c.538+63G>T | Intron (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- RPS8 | c.5-159A>T | Intron (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- RRM2 | n.515A>T | RNA (SNP) | VAF 79/151 reads (52%) | called by muse, varscan2
- SNORD115-13 | n.76G>C | RNA (SNP) | VAF 104/258 reads (40%) | called by muse, mutect2, varscan2
